Surgical pathology report (de-identified scan), TCGA case TCGA-VQ-A91S, project TCGA-STAD (Stomach Adenocarcinoma), tissue source site Barretos Cancer Hospital, specimen TCGA-VQ-A91S-01A (Primary Tumor).

[page 1 of 2]
Collect date:

CLL
ICD-O-3
Adenocarcinoma, tubular 8211/3
Adenocarcinoma, solid & tubular
8230/3 8211/3
Code to highest 8230/3
Site, Body & stomach C16.2
9/18/14

PATHOLOGY REPORT:

PRIMARY SITE: Stomach (Body)

1-Greater omentum:

- Uninvolved by neoplasia.

2- Product of extended gastrectomy (stomach+spleen+pancreatic body and tail):

Gastric adenocarcinoma with the following features:

-Site: gastric cardia and body on lesser curvature.

-Largest tumor size: 11.0 cm.

-Ulceration: present.

-Histologic patterns: solid and tubular.

Pw TSS - 100% tubular.

-Lauren classification: intestinal type.

-Local invasion: mucosa, submucosa, muscularis propria and perivisceral fat tissue.

-Presence of neural invasion.

-Presence of lymphatic invasion.

-Blood vessel invasion: not observed.

-Spleen and pancreatic segment uninvolved by neoplasia.

-Surgical margins uninvolved by neoplasia.

-Number of lymph nodes involved by neoplasia: 2/32.

-Report of examined lymph nodes according to standardization:

Lymph nodes adjacent to specimen (labeled "D"): 1/3

Chain 1 - right paracardic (G): 0/0

Chain 2 - left paracardic (H): 0/0

Chain 3 - lesser curvature (I): 1/4

Chain 4sb - left gastroepiploic (J): 0/2

Chain 4d - right gastroepiploic (K1-K2): 0/6

Chain 5 - suprapyloric (L): 0/1

Chain 6 - infrapyloric (M1-M3): 0/10

Chain 7a - left gastric artery (N1-N2): 0/6

Chain 8a (O): 0/3

Chain 9 - Celiac trunk (P): 0/3

Chain 11p - proximal splenic artery (Q): 0/4

3- Esophageal margin

Uninvolved by neoplasia.

Pw TSS dx discrepancy from
TCGA tumor is 100% tubular.

[page 2 of 2]
TCGA Pathologic Diagnosis Discrepancy Form

V4.00

Instructions: The TCGA Pathologic Diagnosis Discrepancy Form should be completed when the pathologic diagnosis documented on the initial pathology report for a case submitted for TCGA is inconsistent with the diagnosis provided on the Case Quality Control Form completed for the submitted case.

Tissue Source Site (TSS): _____ TSS Identifier: _____ TSS Unique Patient Identifier: _____

Completed By (Interviewer Name on OpenClinica): _____ Completed Date: _____

Diagnosis Information

#	Data Element	Entry Alternatives	Working Instructions
1	Pathologic Diagnosis Provided on Initial Pathology Report	Solid and Tubular	Provide the diagnosis/ histologic subtype(s) documented on the initial pathology report for this case. If the histology for this case is mixed, provide all listed subtypes.
2	Histologic features of the sample provided for TCGA, as reflected on the CQCF.	100% Tubular Adenocarcinoma	Provide the histologic features selected on the TCGA Case Quality Control Form completed for this case.

Discrepancy between Pathology Report and Case Quality Control Form

3	Provide the reason for the discrepancy between the pathology report and the TCGA Case Quality Control Form.	Case was reviewed based on Top Slide to be sent to BCR	Provide a reason describing why the diagnosis on the initial pathology report for this case is not consistent with the diagnosis selected on the TCGA Case Quality Control Form.
4	Name of TSS Reviewing Pathologist or Biorepository Director	_____	Provide the name of the pathologist who reviewed this case for TCGA.

I acknowledge that the above information provided by my institution is true and correct and has been quality controlled.

TSS Reviewing Pathologist or Biorepository Director

Date

I acknowledge that the above information provided by my institution is true and correct and has been quality controlled. The Attending Pathologist or the Department Chairman has been informed or is aware of the above discrepancy in diagnoses.

Principal Investigator Signature

Date

Source: NCI Genomic Data Commons file cfc14fdf-e44b-41c7-a74d-fce5ee2a1906 (TCGA-VQ-A91S.C6267B22-C6F2-4644-AEAB-1F92EF113875.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).